Somatic mutation profile of tumor specimen TCGA-KR-A7K0-01A (aliquot TCGA-KR-A7K0-01A-12D-A33Q-10) from TCGA case TCGA-KR-A7K0, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 65.6 years (23,974 days).
Specimen TCGA-KR-A7K0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e815913-414d-44a8-af90-5ef2dd8fc0cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KR-A7K0-10A (Blood Derived Normal), aliquot TCGA-KR-A7K0-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6671fe03-1594-405d-b6fe-3d6497872280

The open-access MAF lists 109 somatic variants for this specimen: 80 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 28, Nonsense Mutation 6, Frame Shift Del 4, In Frame Del 3, Splice Region 2, Frame Shift Ins 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.109T>G p.S37A | Missense Mutation (SNP) | VAF 24/156 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913228, COSV62688488, COSV62688537, COSV62706597; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABAT | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV51621569; called by muse, mutect2, varscan2
- ABCA13 | c.12478C>G p.Q4160E | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.686); catalogued as COSV71285024; called by muse, mutect2, varscan2
- ADGRL1 | c.1640G>A p.G547E (on ENST00000340736 / NM_001008701.3; = p.G542E on NM_014921.5) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV61564110; called by muse, mutect2, varscan2
- AFF1 | c.2926C>T p.Q976* | Nonsense Mutation (SNP) | VAF 38/95 reads (40%) | catalogued as COSV57118342; called by muse, mutect2, varscan2
- ANTXR1 | c.991T>C p.F331L | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV58011213; called by muse, mutect2, varscan2
- ATCAY | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs777360536, COSV56655033; called by muse, mutect2, varscan2
- ATP1A1 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV55190489; called by muse, mutect2, varscan2
- BNC1 | c.1394G>C p.G465A | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.022); catalogued as COSV61756961; called by muse, mutect2, varscan2
- BTC | c.282C>A p.V94= | Splice Region (SNP) | VAF 103/389 reads (26%) | catalogued as COSV67547425; called by muse, mutect2, varscan2
- C14orf28 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as COSV57333068; called by muse, mutect2, varscan2
- C1R | c.82A>G p.R28G (on ENST00000536053 / NM_001354346.2; = p.R14G on NM_001733.7) | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV56924037; called by muse, mutect2, varscan2
- CCDC8 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56772754; called by muse, mutect2
- CCDC80 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52815788; called by muse, mutect2, varscan2
- CES2 | c.1332G>A p.W444* | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | catalogued as COSV57696542; called by muse, mutect2, varscan2
- CFH | c.1667A>T p.N556I | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV66407056; called by muse, mutect2, varscan2
- CLCN3 | c.1103del p.P368Hfs*29 | Frame Shift Del (DEL) | VAF 47/173 reads (27%) | catalogued as COSV61627566, COSV61628552; called by pindel*, varscan2
- CMPK2 | c.753G>T p.K251N | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV56774279; called by muse, mutect2, varscan2
- CNOT10 | c.1234A>G p.K412E | Missense Mutation (SNP) | VAF 76/257 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.217); catalogued as COSV59391184; called by muse, mutect2, varscan2
- CSHL1 | c.393C>A p.N131K (on ENST00000309894 / NM_022581.3; = p.N37K on NM_001318.4) | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV51987603; called by muse, mutect2
- CTDSPL | c.613G>T p.V205L (on ENST00000273179 / NM_001008392.2; = p.V194L on NM_005808.3) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56201310; called by muse, mutect2, varscan2
- CTPS1 | c.695T>C p.M232T | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.098); catalogued as COSV65452000; called by muse, mutect2, varscan2
- DNAH2 | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.038); catalogued as rs763148087, COSV50013689; called by muse, mutect2, varscan2
- EEF1A1 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 104/321 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV58549515; called by muse, mutect2, varscan2
- EEF1A1 | c.1294A>T p.T432S | Missense Mutation (SNP) | VAF 104/322 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV58548569, COSV58549078; called by muse, mutect2, varscan2
- ERCC2 | c.1853T>G p.V618G | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67267371; called by muse, mutect2, varscan2
- EVC | c.2097G>T p.L699= | Splice Region (SNP) | VAF 35/103 reads (34%) | catalogued as COSV53830760; called by muse, mutect2, varscan2
- FOCAD | c.3031G>T p.D1011Y | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs766397020, COSV58096112; called by muse, mutect2, varscan2
- FRMD1 | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 19/102 reads (19%) | catalogued as COSV51960985; called by muse, mutect2, varscan2
- GARRE1 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55096667, COSV55097870; called by muse, mutect2, varscan2
- GPR132 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs376299075; called by muse, mutect2, varscan2
- GTPBP10 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55986670, COSV55987962; called by muse, mutect2, varscan2
- HELZ | c.3731G>T p.G1244V | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as COSV62377240, COSV62380458; called by muse, mutect2, varscan2
- HMCN1 | c.5130C>A p.Y1710* | Nonsense Mutation (SNP) | VAF 105/195 reads (54%) | catalogued as COSV54887855; called by muse, mutect2, varscan2
- HYDIN | c.11095G>T p.G3699C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66638100; called by muse, mutect2, varscan2
- JADE1 | c.2012G>C p.G671A | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.96); PolyPhen benign (0.039); catalogued as COSV56904981, COSV99886311; called by muse, mutect2, varscan2
- KRT7 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV59330399; called by muse, mutect2, varscan2
- LAT2 | c.116T>G p.I39S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868935686, COSV51920874; called by muse, mutect2, varscan2
- LRFN3 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV55817268; called by muse, mutect2, varscan2
- LRRC4C | c.1636A>G p.I546V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53421434; called by muse, mutect2, varscan2
- MANSC1 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 31/90 reads (34%) | catalogued as COSV67110812; called by muse, mutect2, varscan2
- MTMR6 | c.144A>G p.I48M | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV67808005; called by muse, mutect2, varscan2
- MUC16 | c.12652C>T p.P4218S | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV67455133; called by muse, mutect2, varscan2
- MYADM | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100424881; called by muse, mutect2
- NWD1 | c.3815C>T p.T1272M | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs758051323, COSV60339292; called by muse, mutect2, varscan2
- OR10K2 | c.931C>A p.L311M | Missense Mutation (SNP) | VAF 12/335 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.221); catalogued as COSV100149460; called by muse, mutect2
- OR51E2 | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as rs747842783, COSV67807116, COSV67808893; called by muse, mutect2, varscan2
- PAX1 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV68271371; called by muse, mutect2, varscan2
- PBX2 | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV66708772; called by muse, mutect2, varscan2
- PDHA2 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs755461904, COSV54777743; called by muse, mutect2, varscan2
- PDZD2 | c.5989A>T p.M1997L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV56854382; called by muse, mutect2, varscan2
- PKHD1 | c.11152T>C p.S3718P | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV64384604; called by muse, mutect2, varscan2
- PLEKHA5 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54697085; called by muse, mutect2, varscan2
- PRELID1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs758358635, COSV57463104; called by muse, mutect2, varscan2
- PRKAA1 | c.1628C>A p.T543K | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62629255; called by muse, mutect2, varscan2
- PSD | c.1435A>G p.T479A | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV50043308; called by muse, mutect2, varscan2
- PXK | c.1022T>G p.L341* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as COSV57087765; called by muse, mutect2, varscan2
- RIMBP2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs113895223, COSV55468396; called by muse, mutect2, varscan2
- SPNS1 | c.1492+1G>A p.X498_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | catalogued as rs1384165722, COSV57954117; called by muse, mutect2
- ST6GALNAC1 | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 45/159 reads (28%) | PolyPhen benign (0.135); catalogued as COSV50073820; called by muse, mutect2, varscan2
- ST8SIA4 | c.989C>A p.P330H | Missense Mutation (SNP) | VAF 21/84 reads (25%) | PolyPhen benign (0.198); catalogued as COSV51508242; called by muse, mutect2, varscan2
- TLK2 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 111/408 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58298430; called by muse, mutect2, varscan2
- TMEM192 | c.719A>T p.D240V | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104403714, COSV60584804; called by muse, mutect2, varscan2
- TMPRSS11D | c.725C>A p.S242Y | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV52222396; called by muse, mutect2, varscan2
- TRAPPC9 | c.1406A>G p.Y469C | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as rs1391693665, COSV66895692; called by muse, mutect2, varscan2
- TTC16 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as rs923179592, COSV60160280; called by muse, mutect2, varscan2
- USH2A | c.11305A>T p.M3769L | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV56347537; called by muse, mutect2, varscan2
- USP20 | c.1627C>T p.L543F | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV59612196; called by muse, mutect2, varscan2
- WASHC2A | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 211/671 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99254589; called by muse, mutect2, varscan2
- WFDC1 | c.598T>C p.Y200H | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV54743498; called by muse, mutect2, varscan2
- ZFR | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV54051632; called by muse, varscan2
- ZNF804B | c.2885C>T p.P962L | Missense Mutation (SNP) | VAF 93/281 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV60821701, COSV60826402; called by muse, mutect2, varscan2
- ZSCAN5A | c.588G>C p.Q196H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV54225359; called by muse, mutect2, varscan2
- APOB | c.7155_7159del p.I2386Rfs*4 | Frame Shift Del (DEL) | VAF 57/200 reads (29%) | called by mutect2, pindel, varscan2
- FRRS1 | c.69dup p.P24Sfs*15 | Frame Shift Ins (INS) | VAF 65/268 reads (24%) | called by mutect2, pindel, varscan2
- IBSP | c.470_505del p.E157_E168del | In Frame Del (DEL) | VAF 23/119 reads (19%) | called by mutect2, pindel
- PLXNB2 | c.627_639delinsT p.Y210_T213del | In Frame Del (DEL) | VAF 30/78 reads (38%) | called by pindel, varscan2*
- POU3F2 | c.1159del p.L387Sfs*12 | Frame Shift Del (DEL) | VAF 25/109 reads (23%) | called by mutect2, pindel, varscan2
- UNC5D | c.2604del p.N869Mfs*10 | Frame Shift Del (DEL) | VAF 36/130 reads (28%) | called by mutect2, varscan2
- XPNPEP3 | c.1273_1287del p.Y425_D429del | In Frame Del (DEL) | VAF 30/105 reads (29%) | called by mutect2, pindel, varscan2
- ANKLE2 | c.1281A>C p.V427= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV61708513; called by muse, mutect2, varscan2
- CNGA4 | c.1626C>T p.P542= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs560979109, COSV66005473; called by muse, mutect2, varscan2
- DEPDC1B | c.636C>A p.V212= | Silent (SNP) | VAF 50/152 reads (33%) | catalogued as COSV54008915; called by muse, mutect2, varscan2
- DOCK2 | c.2409G>T p.L803= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV56950546; called by muse, mutect2, varscan2
- ENDOD1 | c.186T>G p.A62= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV53589073; called by muse, mutect2, varscan2
- EPHA5 | c.378C>A p.I126= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs55882537, COSV56637421; called by muse, mutect2, varscan2
- FUT8 | c.288G>A p.Q96= | Silent (SNP) | VAF 43/135 reads (32%) | catalogued as COSV61282072; called by muse, mutect2, varscan2
- GON4L | c.2877C>T p.D959= | Silent (SNP) | VAF 37/176 reads (21%) | catalogued as COSV55190316, COSV99674838; called by muse, mutect2, varscan2
- LBH | c.201A>G p.E67= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV68049236; called by muse, mutect2, varscan2
- LRFN2 | c.1743C>T p.G581= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs147506870; called by muse, mutect2, varscan2
- MAP2 | c.5196C>T p.F1732= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as COSV52285846; called by muse, mutect2, varscan2
- MYOM1 | c.5004G>A p.E1668= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV55288090; called by muse, mutect2, varscan2
- NAA25 | c.2163C>G p.S721= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs779341242, COSV55703183; called by muse, mutect2, varscan2
- OBSCN | c.21876C>T p.A7292= | Silent (SNP) | VAF 168/360 reads (47%) | catalogued as rs372263588; called by muse, mutect2, varscan2
- PPP2R1B | c.141A>G p.L47= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV59535118; called by muse, mutect2, varscan2
- PPT1 | c.864T>C p.H288= (on ENST00000433473; = p.H289= on NM_000310.4) | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV61223048; called by muse, mutect2, varscan2
- PRPF4B | c.720A>G p.K240= | Silent (SNP) | VAF 47/170 reads (28%) | catalogued as COSV61783724; called by muse, mutect2, varscan2
- RAG1 | c.2655G>A p.L885= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV55024430; called by muse, mutect2, varscan2
- RUSC1 | c.1122C>A p.L374= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV52738834; called by muse, mutect2, varscan2
- SCN7A | c.1998C>A p.L666= | Silent (SNP) | VAF 78/235 reads (33%) | catalogued as COSV101313170, COSV69270259; called by muse, mutect2, varscan2
- STK32A | c.897T>C p.I299= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV60416786; called by muse, mutect2, varscan2
- SYT7 | c.45C>T p.R15= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs547867914, COSV55654651; called by muse, mutect2, varscan2
- TEX15 | c.8076G>T p.G2692= (on ENST00000256246; = p.G3075= on NM_001350162.2) | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as rs547808449, COSV56343880; called by muse, mutect2, varscan2
- TGS1 | c.198T>C p.G66= | Silent (SNP) | VAF 53/195 reads (27%) | catalogued as COSV52699026; called by muse, mutect2, varscan2
- TLK1 | c.2064A>G p.T688= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV62629608; called by muse, mutect2, varscan2
- TTN | c.67848T>C p.Y22616= (on ENST00000591111; = p.Y15192= on NM_003319.4) | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV59951082; called by muse, mutect2, varscan2
- TULP1 | c.1296C>T p.N432= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs752893076, COSV57692234; called by muse, mutect2, varscan2
- VARS2 | c.3012C>T p.Y1004= | Silent (SNP) | VAF 57/143 reads (40%) | catalogued as COSV58911789; called by muse, mutect2, varscan2
- Y_RNA | chr14:50083909 T>C | 5'Flank (SNP) | VAF 43/154 reads (28%) | called by muse, mutect2, varscan2
